Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QU, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QU-01A (Primary Tumor).

[page 1 of 2]
Macroscopic examination :

1) The part of thymectomy sent fresh is 37 g . It is addressed identified.

Presence of a nodule measuring 4 x 3.5 x 2 cm, whitish appearance, although limited , lobulated .

Samples storied were made.

2) A fragment of innominate vein measuring 3.5 x 2 cm .

Microscopic examination :

1) Thymus :

1A to 1I) Tumour:

The tumor has a lobulated appearance , separated by thick pads fibrosis. These
a biphasic tumor with epithelial quota fusiform aspect, together
in beamlets , in nests , sometimes in rosettes , surrounded by a second contingent fact
relatively regular lymphocytes. The tumor is poorly defined . It infiltrates
several points the tumor capsule and has a few small nodules scattered
the single fat. In contrast, section slices labeled with ink
go into healthy tissue. Some tracks appear richer in cells
epithelial cells, with a smaller contingent lymphocytic yet always
present. Presence also some areas with clear perivascular spaces
(1G block).

After immunohistochemistry , epithelial cells express cytokeratin
KL1 and AE1/AE3 . Epithelial cells also express CD20. However, they
express neither the CD5 or CD117 . Accompanying lymphocytes express CD5 and
CD1a .

1J , 1K) adjacent parenchyma thymic :

ICD O-3
Thymoma, type AB, malignant 8582/3
Site: Thymus CB79
QW 4/2/14

[page 2 of 2]
The adjacent parenchyma thymic involution has a fat marked .

2) innominate vein :

The samples examined correspond to large vascular structures lined with a muscular wall and surrounded by fatty tissue. Presence also two small lymph nodes.

Conclusion :

Thymoma 4 cm in diameter, in type AB , with minimal invasion of the capsule.

Complete surgical resection.

According to the classification of Masaoka changed, it is a grade IIa .

Dr.

electronic signature

Source: NCI Genomic Data Commons file 3bf79d1a-bfef-45d9-a0d3-2ec4123146ee (TCGA-4V-A9QU.7EB875EC-AD69-4332-9AB6-47F35F412F02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).